Somatic mutation profile of tumor specimen 0DA8LI from CCDI case PBBJMC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.5 years (4,207 days).
Specimen 0DA8LI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f42f7630-925d-4605-8c05-6cbb08d314a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA8L7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c415e5f-0f62-4a0c-8cd2-c31b736ec34f

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTLN | c.1907T>G p.L636* | Nonsense Mutation (SNP) | VAF 125/317 reads (39%) | catalogued as COSV52081723; called by muse, mutect2, varscan2
- NBEAL2 | c.4721G>A p.R1574H | Missense Mutation (SNP) | VAF 212/442 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); catalogued as rs200266051; called by muse, mutect2, varscan2
- PROM2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 193/398 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs758232721, COSV100468612; called by muse, mutect2, varscan2
- SUSD2 | c.2108C>T p.T703I | Missense Mutation (SNP) | VAF 172/324 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1324750281; called by muse, mutect2, varscan2
- COL28A1 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 36/628 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 26/1035 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SYNE2 | c.17595G>C p.L5865F | Missense Mutation (SNP) | VAF 315/646 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TPRG1L | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 64/418 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 22/632 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- POLR3D | c.543G>T p.P181= | Silent (SNP) | VAF 49/384 reads (13%) | called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 22/626 reads (4%) | catalogued as rs1267156464; called by muse, mutect2
- ZNF202 | c.372G>A p.L124= | Silent (SNP) | VAF 64/386 reads (17%) | catalogued as rs764505380; called by muse, varscan2
- COG2 | c.2115+75C>T | Intron (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
